Somatic mutation profile of tumor specimen 3b177fd6-e7d2-4312-bec7-4a253d (aliquot 3b177fd6-e7d2-4312-bec7-4a253d_D6_1) from CPTAC case 11BR028, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 55.3 years (20,196 days).
Specimen 3b177fd6-e7d2-4312-bec7-4a253d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2ed7be7-9881-449c-8555-fe85e3f25130.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 82887429-6fff-4bb0-8664-ce4d22 (Blood Derived Normal), aliquot 82887429-6fff-4bb0-8664-ce4d22_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74b804a2-344d-4c44-9fb1-8fcba52c843f

The open-access MAF lists 146 somatic variants for this specimen: 90 protein-altering or splice-affecting, 42 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 42, Intron 7, Nonsense Mutation 5, Frame Shift Del 4, 3'UTR 3, RNA 2, In Frame Del 2, 5'UTR 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPTL2 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52219303; called by muse, mutect2, varscan2
- ATP6V0A2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.611); catalogued as rs199633614; called by muse, mutect2, varscan2
- ATP7A | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 73/404 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58445529; called by muse, mutect2, varscan2
- BCL11A | c.2371G>A p.D791N (on ENST00000335712 / NM_001365609.1; = p.D825N on NM_022893.4) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); catalogued as COSV59630811; called by muse, mutect2
- BSN | c.5428C>A p.P1810T | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV56517012; called by muse, mutect2, varscan2
- CRB2 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 69/399 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs1313497379; called by muse, mutect2, varscan2
- DHX57 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 79/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274227841, COSV54887539; called by muse, mutect2, varscan2
- DLGAP3 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766787160, COSV52399154; called by muse, mutect2, varscan2
- DPAGT1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776632995, CM126444, COSV53829477; called by muse, mutect2, varscan2
- DYM | c.409_411del p.P137del | In Frame Del (DEL) | VAF 88/355 reads (25%) | catalogued as rs769648023; called by mutect2, pindel, varscan2
- EIF4G2 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.127); catalogued as rs377023918; called by muse, mutect2, varscan2
- FRS2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.249); catalogued as rs769491241, COSV54724649; called by mutect2, varscan2
- GABRB2 | c.1228G>T p.E410* (on ENST00000274547; = p.E372* on NM_000813.3) | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99196631; called by muse, mutect2, varscan2
- GLIS3 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs559065074, COSV100174335; called by muse, mutect2, varscan2
- H2BC11 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.943); catalogued as rs933046951; called by muse, mutect2, varscan2
- JPH2 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 92/406 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.283); catalogued as rs200149713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM1B | c.2021G>C p.S674T (on ENST00000449850; = p.S441T on NM_153042.4) | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV52809592, COSV52811801; called by muse, mutect2, varscan2
- KRT1 | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 62/412 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1375564720, COSV52865403; called by muse, mutect2, varscan2
- MCL1 | c.197C>A p.P66Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs747459222; called by muse, mutect2, varscan2
- NCOR2 | c.3735G>C p.R1245S | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs1236663114; called by muse, mutect2, varscan2
- NEXN | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746761862; called by muse, mutect2, varscan2
- NKX2-1 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61390392; called by muse, mutect2, varscan2
- NKX3-2 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as rs1439794000; called by muse, mutect2, varscan2
- NUF2 | c.1071C>G p.F357L | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs772985332; called by muse, mutect2, varscan2
- PCDHB3 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV50586567; called by muse, mutect2, varscan2
- PHF7 | c.632_633del p.K211Rfs*38 | Frame Shift Del (DEL) | VAF 31/152 reads (20%) | catalogued as rs1215033283; called by mutect2, pindel, varscan2
- PRKCA | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV99434997; called by muse, mutect2, varscan2
- PRXL2C | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as rs768610987; called by muse, mutect2, varscan2
- PTEN | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as CM142087, HM971504, COSV64288951, COSV64296078, COSV64302138; called by muse, mutect2, varscan2
- REPS1 | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57812680; called by muse, mutect2, varscan2
- SART1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV56711700, COSV56712123; called by muse, mutect2, varscan2
- SERPINB8 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV54639476; called by muse, mutect2, varscan2
- SH3BP5 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs199531009, COSV53743013; called by muse, mutect2, varscan2
- SHC3 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs779875669; called by muse, mutect2, varscan2
- SI | c.3674G>C p.G1225A | Missense Mutation (SNP) | VAF 71/520 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52284184; called by muse, mutect2, varscan2
- SLC8A1 | c.1745G>C p.R582T | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs774791442; called by muse, mutect2
- SPARCL1 | c.1721T>C p.I574T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs200337847, COSV56802485; called by muse, mutect2, varscan2
- SPEG | c.5155G>C p.D1719H | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56678461; called by muse, mutect2, varscan2
- STK32C | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759946918, COSV104404775; called by muse, mutect2, varscan2
- THEMIS | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 137/217 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV64075110; called by muse, mutect2, varscan2
- TMEM94 | c.2902G>A p.V968M | Missense Mutation (SNP) | VAF 31/631 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58597990; called by muse, mutect2
- TRPS1 | c.3101C>T p.P1034L (on ENST00000220888 / NM_001330599.2; = p.P1047L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/532 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200876887, CD155378, COSV55260509; called by muse, mutect2, varscan2
- UNC13C | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99520998; called by muse, mutect2, varscan2
- ZMYND15 | c.1651G>T p.E551* (on ENST00000433935 / NM_001136046.3; = p.E512* on NM_032265.2) | Nonsense Mutation (SNP) | VAF 38/164 reads (23%) | catalogued as rs143021472; called by muse, mutect2, varscan2
- ZNF607 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.392); catalogued as rs776158855, COSV62206208; called by muse, mutect2, varscan2
- ACBD6 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 33/288 reads (11%) | called by muse, mutect2, varscan2
- AL031777.2 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- ANKFN1 | c.3697G>C p.A1233P (on ENST00000653862; = p.A1086P on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/1213 reads (5%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); called by muse, mutect2
- BTBD7 | c.1540del p.S514Lfs*15 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | called by mutect2, pindel, varscan2
- C3orf56 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH26 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.295); called by muse, mutect2
- CFAP43 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.027); called by muse, mutect2
- CLK4 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CNST | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CNTN3 | c.394G>T p.V132L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CTTN | c.1445-1G>C p.X482_splice | Splice Site (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
- DDX21 | c.1763C>A p.P588H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- DLGAP2 | c.1214C>A p.P405Q | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2
- EPB41 | c.782C>T p.S261F (on ENST00000343067 / NM_001166005.2; = p.S52F on NM_004437.4) | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- FANCM | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- GPATCH11 | c.670G>A p.E224K (on ENST00000409774; = p.E202K on NM_174931.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GTPBP1 | c.25_33del p.A9_D11del | In Frame Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- H6PD | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2
- HSPBP1 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- LMOD1 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRP2 | c.2850C>G p.I950M | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- MPV17 | c.257T>A p.L86Q | Missense Mutation (SNP) | VAF 105/456 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- NLRP11 | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- OPTN | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR13D1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ORC4 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLA2G4A | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 189/355 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PPM1E | c.1900T>C p.S634P | Missense Mutation (SNP) | VAF 107/564 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RFX7 | c.2491C>G p.H831D (on ENST00000559447 / NM_001368074.1; = p.H928D on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2
- RIN1 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SLC4A3 | c.3621+1del | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel, varscan2
- SRPK3 | c.1484C>G p.S495* | Nonsense Mutation (SNP) | VAF 38/142 reads (27%) | called by muse, mutect2, varscan2
- SYNE1 | c.7269G>C p.L2423F (on ENST00000367255 / NM_182961.4; = p.L2430F on NM_033071.3) | Missense Mutation (SNP) | VAF 271/467 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TAB3 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- THSD7A | c.2528G>A p.C843Y | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TIGD5 | c.422C>A p.P141Q | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by mutect2, varscan2
- TMC7 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRAPPC12 | c.1634G>C p.G545A | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- TTC6 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TXK | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- UNC13D | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 49/1281 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2
- UNC13D | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 43/1286 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2
- YRDC | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB12 | c.1001A>C p.K334T | Missense Mutation (SNP) | VAF 104/460 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.073); called by muse, varscan2
- ZNHIT2 | c.135del p.Y46Tfs*19 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | called by mutect2, pindel, varscan2
- AAR2 | c.942C>T p.F314= | Silent (SNP) | VAF 51/238 reads (21%) | catalogued as rs748440774, COSV57924973; called by muse, mutect2, varscan2
- ABHD5 | c.72C>T p.L24= | Silent (SNP) | VAF 42/332 reads (13%) | catalogued as rs1424007074; called by muse, mutect2, varscan2
- ACOX2 | c.315C>T p.Y105= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs146624586; called by muse, mutect2, varscan2
- ALPK3 | c.3075G>A p.Q1025= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as COSV51929440, COSV99360675, COSV99361152; called by muse, mutect2, varscan2
- ANGPT1 | c.267G>A p.V89= | Silent (SNP) | VAF 48/146 reads (33%) | called by muse, mutect2, varscan2
- ARMC9 | c.1959C>T p.P653= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs755043246, COSV100590099; called by muse, varscan2
- C1QL2 | c.195C>T p.L65= | Silent (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- CHD1 | c.3276T>C p.S1092= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs1193449839; called by muse, mutect2, varscan2
- COL6A5 | c.2103C>T p.I701= | Silent (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- CRB2 | c.492C>T p.G164= | Silent (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- DMTF1 | c.1401C>T p.I467= | Silent (SNP) | VAF 32/155 reads (21%) | called by muse, mutect2, varscan2
- DTNA | c.1425G>A p.L475= | Silent (SNP) | VAF 63/345 reads (18%) | catalogued as COSV99315497; called by muse, mutect2, varscan2
- ECH1 | c.411G>A p.R137= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as COSV55490333; called by muse, mutect2, varscan2
- ELMO1 | c.1596G>A p.P532= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs369838763; called by muse, mutect2, varscan2
- EXT1 | c.180C>T p.D60= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as rs906171134, CD113082; called by muse, mutect2, varscan2
- GSK3A | c.309C>T p.V103= | Silent (SNP) | VAF 29/197 reads (15%) | catalogued as rs1019077240; called by muse, mutect2, varscan2
- IQCN | c.798C>T p.I266= | Silent (SNP) | VAF 24/180 reads (13%) | catalogued as COSV66573979; called by muse, varscan2
- IQSEC1 | c.2184C>T p.L728= | Silent (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- KCNH3 | c.1659C>T p.D553= | Silent (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- LRP1 | c.6669C>T p.P2223= | Silent (SNP) | VAF 43/241 reads (18%) | catalogued as rs774487971; called by muse, mutect2, varscan2
- LTBP1 | c.4353C>T p.Y1451= (on ENST00000404816 / NM_206943.4; = p.Y1125= on NM_000627.4) | Silent (SNP) | VAF 36/135 reads (27%) | called by muse, mutect2, varscan2
- LY75 | c.375G>A p.L125= | Silent (SNP) | VAF 41/161 reads (25%) | called by muse, mutect2, varscan2
- MAN2A2 | c.375G>A p.Q125= | Silent (SNP) | VAF 13/252 reads (5%) | called by muse, mutect2
- MAP3K1 | c.894A>T p.P298= | Silent (SNP) | VAF 47/270 reads (17%) | called by muse, mutect2, varscan2
- MPV17 | c.258G>T p.L86= | Silent (SNP) | VAF 107/468 reads (23%) | catalogued as COSV51992321; called by muse, mutect2, varscan2
- NDN | c.300G>A p.Q100= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as rs1385480423, COSV59358687; called by muse, mutect2, varscan2
- NYNRIN | c.2199C>T p.L733= | Silent (SNP) | VAF 45/275 reads (16%) | catalogued as rs541733075; called by muse, mutect2, varscan2
- OR1J4 | c.165T>G p.L55= | Silent (SNP) | VAF 37/231 reads (16%) | catalogued as rs774121231; called by muse, mutect2, varscan2
- OR5D13 | c.159C>T p.L53= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- POLM | c.558C>G p.L186= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV54243292; called by muse, mutect2, varscan2
- PTPRO | c.1668C>T p.G556= | Silent (SNP) | VAF 82/174 reads (47%) | catalogued as rs376460659; called by muse, mutect2, varscan2
- SERPINB5 | c.1086A>G p.K362= | Silent (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- SGMS2 | c.63G>A p.T21= | Silent (SNP) | VAF 57/177 reads (32%) | catalogued as rs565028161, COSV62989230; called by muse, mutect2, varscan2
- SNAP25 | c.378G>A p.Q126= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV54776019; called by muse, mutect2, varscan2
- SYNE2 | c.1299G>C p.L433= | Silent (SNP) | VAF 38/394 reads (10%) | catalogued as COSV59948217; called by muse, mutect2
- TTC19 | c.240C>T p.A80= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as rs759361415; called by muse, mutect2, varscan2
- USP36 | c.2475A>G p.S825= | Silent (SNP) | VAF 79/244 reads (32%) | catalogued as rs745471043; called by muse, mutect2, varscan2
- WDR43 | c.730C>A p.R244= | Silent (SNP) | VAF 3/64 reads (5%) | catalogued as COSV99942939; called by muse, mutect2
- ZBTB37 | c.1329C>T p.I443= | Silent (SNP) | VAF 71/632 reads (11%) | catalogued as COSV62931643; called by muse, mutect2, varscan2
- ZC3H11A | c.222A>G p.G74= | Silent (SNP) | VAF 30/372 reads (8%) | called by muse, mutect2
- ZHX3 | c.2106C>T p.V702= | Silent (SNP) | VAF 66/181 reads (36%) | catalogued as rs766118155; called by muse, mutect2, varscan2
- ZNF764 | c.423G>A p.S141= | Silent (SNP) | VAF 279/408 reads (68%) | catalogued as rs1374520516, COSV53222173; called by muse, mutect2, varscan2
- AC064807.1 | n.1174G>C | RNA (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2
- ACSF3 | c.*1194C>G | 3'UTR (SNP) | VAF 41/147 reads (28%) | catalogued as COSV58077935; called by muse, mutect2, varscan2
- ADAMTS6 | c.2575+26C>T | Intron (SNP) | VAF 31/197 reads (16%) | called by muse, mutect2, varscan2
- CR1 | c.-3A>G | 5'UTR (SNP) | VAF 29/258 reads (11%) | catalogued as COSV65463861; called by muse, mutect2, varscan2
- CRYM-AS1 | n.333T>G | RNA (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- CTTN | c.*1209G>A | 3'UTR (SNP) | VAF 29/156 reads (19%) | catalogued as COSV100097501; called by muse, mutect2, varscan2
- KCNAB2 | c.119+9829G>T | Intron (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- NPEPPS | c.541-162C>G | Intron (SNP) | VAF 57/195 reads (29%) | called by muse, mutect2, varscan2
- RGL4 | c.*6C>G | 3'UTR (SNP) | VAF 26/198 reads (13%) | called by muse, mutect2, varscan2
- SFXN5 | c.945+4036A>G | Intron (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- SLC38A2 | c.564-44G>C | Intron (SNP) | VAF 25/124 reads (20%) | called by muse, mutect2, varscan2
- TARS1 | c.330-896dup | Intron (INS) | VAF 25/176 reads (14%) | called by mutect2, pindel, varscan2
- TTN | c.10303+2662C>G | Intron (SNP) | VAF 15/209 reads (7%) | called by muse, mutect2
- ZNF880 | chr19:52390352 C>T | 3'Flank (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
